FM case AD7373 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Thymus.
https://portal.gdc.cancer.gov/cases/9b5d5a18-e3ed-4992-8e5f-d262d3aa50cd

Male, 73.2 years: Carcinoma, NOS (ICD-O-3 8010/3) of the thymus; metastasis biopsied or resected from the thorax. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
